Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4698, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4698-01A (Primary Tumor).

FINAL DIAGNOSIS

PART 1: LEFT PERIHILAR TISSUE, EXCISION –

HIGH GRADE CARCINOMA WITH EXTENSIVE NECROSIS, INVADING SKELETAL MUSCLE. CARCINOMATOUS ANGIOLYMPHATIC EMBOLI IDENTIFIED (SLIDE 1B).

PART 2: LEFT RENAL VEIN CUFF, EXCISION –

- A. SEGMENT OF LARGE VEIN OCCLUDED BY HIGH GRADE, FOCALLY SARCOMATOID CARCINOMA.
- B. CARCINOMA INVADES THROUGH VEIN WALL INTO PERIVENULAR ADVENTITIA.

PART 3: TUMOR THROMBUS, EXCISION –

SARCOMATOID CARCINOMA WITH NECROSIS.

PART 4: LEFT KIDNEY, SPLEEN, TAIL OF PANCREAS AND ASSOCIATED SOFT TISSUE, RESECTION –

- A. HIGH-GRADE, PARTIALLY CYSTIC, PARTIALLY SARCOMATOID CARCINOMA, FAVOR DEDIFFERENTIATED RENAL CELL CARCINOMA, 10.5 CM. PROBABLE SMALL CLEAR CELL CARCINOMATOUS COMPONENT PRESENT (SLIDE 4E) (see comment).
- B. CARCINOMA INVOLVES THE UPPER POLE OF THE KIDNEY, PERIRENAL ADIPOSE TISSUE, GEROTA'S FASCIA, TAIL OF PANCREAS AND RETROPERITONEAL SOFT TISSUE.
- C. LARGE OCCLUSIVE TUMOR THROMBUS IS PRESENT IN THE MAIN RENAL VEIN, EXTENDING TO THE RENAL VEIN SURGICAL RESECTION MARGIN (SLIDE 4D). SMALL VESSEL ANGIOLYMPHATIC INVASION IS ALSO IDENTIFIED (SLIDE 4L).
- D. BRISK HOST LYMPHOCYTIC REACTION.
- E. BENIGN URETER, SPLEEN, ACCESSORY SPLEEN AND SIX (6) RENAL AND PERISPLENIC LYMPH NODES.
- F. CARCINOMA IS PRESENT AT THE MAIN RENAL VEIN SURGICAL RESECTION MARGIN AND GEROTA'S FASCIA RESECTION MARGIN. ALL OTHER SURGICAL RESECTION MARGINS ARE BENIGN.
- G. PATHOLOGIC STAGE (ASSUMING PRIMARY RENAL CELL CARCINOMA): pT4 Nx Mx; G4 (see comment).

PART 5: LEFT PSOAS MUSCLE, EXCISION –

SARCOMATOID CARCINOMA INFILTRATING SKELETAL MUSCLE.

Source: NCI Genomic Data Commons file 245ec885-15b8-426c-9c7a-3e8ff266c4b8 (TCGA-B0-4698.28620D84-2435-4911-91B9-758741352C47.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).